Gene-level copy-number profile of tumor specimen TCGA-77-8138-01A from TCGA case TCGA-77-8138, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 74.5 years (27,225 days).
Specimen TCGA-77-8138-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.bbda3a32-69bb-4732-a528-abb95ec037b3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-8138-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ac1dcffc-0a50-408b-9307-9eb1b6e0bcee

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,410; copy number 2: 23,680; copy number 3: 17,706; copy number 4: 10,765; copy number 5: 3,723; copy number 6: 132; copy number 7: 550; copy number 8: 849.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-8138-01A-11D-2243-01): tumor purity 0.23, ploidy 2.99, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,254 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 5–7 (broad region; genes not listed).
- chr8:41,490,396–145,066,685, 1,607 genes, copy number 5 (broad region; genes not listed).
- chr12:66,767–34,219,246, 849 genes, copy number 8 (broad region; genes not listed).
- chr15:94,231,538–94,483,952, 1 gene, copy number 5 (within-gene range 3–5): MCTP2.
- chr15:94,455,469–98,320,237, 66 genes, copy number 5 (broad region; genes not listed).
- chr19:18,340,598–20,983,210, 132 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr19:27,638,483–58,605,223, 1,686 genes, copy number 5 (broad region; genes not listed).
- chr20:9,537,370–9,839,076, 1 gene, copy number 5 (within-gene range 4–5): PAK5.
- chr20:9,835,556–22,284,029, 202 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,410. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
